CCDI case PBBXJI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/bc1117db-d966-4e9e-8f84-a895d787b482

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Tumor cells, benign: ICD-O-3 morphology code: 8001/0; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 17.5 years (6,399 days).

Biospecimens (3 samples)
- Sample 0DQQBQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample 0DQQC8: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DQQCJ: Tissue type: Normal; Specimen type: Peripheral Whole Blood. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
